Somatic mutation profile of tumor specimen ALCH-B3ZR-TTP1-A (aliquot ALCH-B3ZR-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.8 years (24,036 days).
Specimen ALCH-B3ZR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 786674ca-e13f-4396-aaa7-e8c9d6426b3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZR-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZR-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cab9950f-d092-4784-b163-2eb23ff74e32

The open-access MAF lists 394 somatic variants for this specimen: 267 protein-altering or splice-affecting, 79 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 79, Nonsense Mutation 24, Intron 22, RNA 13, Splice Region 7, Splice Site 5, 3'UTR 4, 5'UTR 4, 5'Flank 4, Frame Shift Del 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 24/338 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ACBD7 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs1415067546; called by muse, mutect2
- ADAMTS18 | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 36/571 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1346395079, COSV51422997; called by muse, mutect2
- AOX1 | c.669+1G>A p.X223_splice | Splice Site (SNP) | VAF 17/172 reads (10%) | catalogued as rs768088310; called by muse, mutect2
- APOB | c.12181G>C p.E4061Q | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as CD920828, COSV51929766, COSV99268382; called by muse, mutect2
- AR | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101019842; called by muse, mutect2
- ARHGEF6 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99166566; called by muse, mutect2
- BUB3 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.364); catalogued as COSV100378749; called by muse, mutect2
- C16orf71 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV58507614; called by muse, mutect2, varscan2
- CCDC168 | c.16980C>A p.D5660E | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as rs1172736628; called by muse, mutect2
- CD19 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV61189395; called by muse, mutect2, varscan2
- CD1C | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs769112361, COSV63805575; called by muse, mutect2
- CMPK2 | c.911G>T p.R304I | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56774639; called by muse, mutect2
- CMTR1 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs372628932; called by muse, mutect2, varscan2
- COL4A6 | c.1989C>A p.Y663* | Nonsense Mutation (SNP) | VAF 20/198 reads (10%) | catalogued as COSV100563316, COSV57868368; called by muse, mutect2, varscan2
- DCAF8L2 | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.15); catalogued as COSV101445684; called by muse, mutect2
- ELF3 | c.1052T>A p.V351D | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62840664; called by muse, mutect2
- ENOX1 | c.1865C>A p.T622K | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV54902024; called by muse, mutect2
- EPHA5 | c.2532G>C p.W844C | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56632171; called by muse, mutect2
- EPHA7 | c.231G>C p.M77I | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100992561; called by muse, mutect2
- EPHA8 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761039847; called by muse, mutect2, varscan2
- FBN2 | c.1748G>C p.G583A | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52531422; called by muse, mutect2
- FLI1 | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 50/612 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs759764204; called by muse, mutect2
- GFER | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM092920; called by muse, mutect2
- GIMAP5 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs927435790, COSV57530170; called by muse, mutect2
- GLDC | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 24/352 reads (7%) | catalogued as CD061418; called by muse, mutect2
- GPRIN3 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 12/358 reads (3%) | catalogued as rs1296008216; called by muse, mutect2
- GRIP1 | c.2038G>T p.G680W (on ENST00000359742 / NM_001379345.1; = p.G628W on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54029492, COSV54033744; called by muse, mutect2, varscan2
- GRM5 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV59602069, COSV59624362; called by muse, mutect2
- HECW2 | c.2603G>A p.R868K | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs772066031, COSV53665846; called by muse, mutect2
- IAPP | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53714940; called by muse, mutect2
- ICE1 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 13/232 reads (6%) | catalogued as COSV99664804; called by muse, mutect2
- IGSF10 | c.3296C>T p.S1099L | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs560889574, COSV56790282; called by muse, mutect2, varscan2
- IL1R2 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746138452; called by muse, mutect2
- INPP4B | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV53740510; called by muse, mutect2
- JCAD | c.914G>T p.R305M | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64757754; called by muse, mutect2
- KALRN | c.3839G>A p.R1280Q | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1032511540; called by muse, mutect2
- KCNH4 | c.1438C>A p.R480S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99237037; called by muse, mutect2
- LIMCH1 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100574330; called by muse, mutect2
- LIPI | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.999); catalogued as COSV60708200; called by muse, mutect2
- LRP1B | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 12/188 reads (6%) | catalogued as COSV67213914; called by muse, mutect2
- MAP1A | c.5819G>C p.S1940T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV55809119; called by muse, mutect2, varscan2
- MDFIC | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs995317109; called by muse, mutect2, varscan2
- METTL1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs930650442, COSV99141661; called by muse, mutect2
- MTRNR2L1 | c.51C>G p.D17E | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as COSV71835001; called by muse, mutect2
- MUC12 | c.11059A>T p.S3687C (on ENST00000379442; = p.S3544C on NM_001164462.1) | Missense Mutation (SNP) | VAF 46/812 reads (6%) | SIFT deleterious (0.02); catalogued as rs750515421; called by muse, mutect2
- MUC16 | c.16340C>A p.S5447* | Nonsense Mutation (SNP) | VAF 23/215 reads (11%) | catalogued as COSV67455338; called by muse, mutect2, varscan2
- MYO19 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778836093; called by muse, mutect2
- NECTIN3 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV60552183; called by muse, mutect2
- NLRP5 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.972); catalogued as COSV66763095; called by muse, mutect2, varscan2
- NPR1 | c.2556C>G p.I852M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV64118132; called by muse, mutect2
- NRG1 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs75920624, COSV55149148; called by muse, mutect2
- NRXN1 | c.4295C>A p.S1432* | Nonsense Mutation (SNP) | VAF 22/332 reads (7%) | catalogued as COSV60498659; called by muse, mutect2
- OR1J4 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV61589572; called by muse, mutect2
- OR5AS1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100546429; called by muse, mutect2
- OR5D13 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as COSV62333400; called by muse, mutect2
- OR6Y1 | c.306C>A p.C102* | Nonsense Mutation (SNP) | VAF 28/382 reads (7%) | catalogued as COSV99043895; called by muse, mutect2
- PAPPA2 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV62781417; called by muse, mutect2
- PCNX3 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765775232; called by muse, mutect2
- PDYN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370283678, COSV54101461; ClinVar: uncertain significance; called by muse, mutect2
- PGK2 | c.1007G>C p.W336S | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59164125; called by muse, mutect2, varscan2
- PIK3CB | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV56689741; called by muse, mutect2
- PLEKHA5 | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1305542366; called by muse, mutect2
- PPFIA2 | c.1901C>A p.S634* | Nonsense Mutation (SNP) | VAF 22/379 reads (6%) | catalogued as COSV61050924; called by muse, mutect2
- PTPRD | c.2016C>A p.Y672* | Nonsense Mutation (SNP) | VAF 40/456 reads (9%) | catalogued as rs1027099282; called by muse, mutect2
- PTPRT | c.3336C>G p.I1112M | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62018195; called by muse, mutect2, varscan2
- RALYL | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72817298; called by muse, mutect2
- RNF122 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as rs753839300; called by muse, mutect2
- RPL13 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.13); catalogued as rs1440944603; called by muse, mutect2
- RPRM | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 16/164 reads (10%) | catalogued as COSV57988711; called by muse, mutect2, varscan2
- RYR2 | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV63682160; called by muse, mutect2
- RYR2 | c.4090G>C p.E1364Q | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63692116; called by muse, mutect2
- SCN3A | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51814587; called by muse, mutect2
- SHCBP1 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as COSV57646448, COSV57649777; called by muse, mutect2
- SPANXN4 | c.171del p.K58Rfs*29 | Frame Shift Del (DEL) | VAF 21/190 reads (11%) | catalogued as COSV65141719; called by mutect2, pindel, varscan2
- STXBP5L | c.1738C>A p.L580I | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV56521068; called by muse, mutect2
- TAB3 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.175); catalogued as COSV55835678; called by muse, mutect2
- TENM3 | c.7448C>G p.A2483G | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV69310647; called by muse, mutect2
- TGFBRAP1 | c.2537G>T p.S846I | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV51514389; called by muse, mutect2
- TLDC2 | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs770451659; called by muse, mutect2
- TLE4 | c.699A>T p.K233N | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1192004879, COSV54640660; called by muse, mutect2
- TMEM50A | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.597); catalogued as COSV65486923; called by muse, mutect2
- TRGC1 | c.476G>C p.C159S | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1317653904; called by muse, mutect2, varscan2
- TSHR | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 32/452 reads (7%) | catalogued as CM107563, COSV53313995, COSV99993137; called by muse, mutect2
- TST | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs368128835; called by muse, mutect2
- UBE2C | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1271204292; called by muse, mutect2
- UBR5 | c.6190G>T p.E2064* | Nonsense Mutation (SNP) | VAF 12/202 reads (6%) | catalogued as COSV55302710; called by muse, mutect2
- UGGT2 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs1056341076, COSV65025355; called by muse, mutect2
- UGT1A6 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as rs1369651424; called by muse, mutect2
- UNC80 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55907783; called by muse, mutect2
- UNC80 | c.8521G>T p.V2841L | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV55887750; called by muse, mutect2
- USH2A | c.9136C>A p.P3046T | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240439; called by muse, mutect2
- USP26 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.464); catalogued as rs776467655; called by muse, mutect2
- ZEB1 | c.3250G>A p.G1084R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs914827545, COSV100315186; called by muse, varscan2
- ZNF648 | c.1396C>A p.H466N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374659; called by muse, mutect2
- ABCA4 | c.6784C>A p.P2262T | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ABCG8 | c.1519T>A p.Y507N | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ADAM11 | c.638C>A p.S213* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | called by mutect2, varscan2
- ADAM18 | c.2061C>G p.N687K | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2
- ADAM23 | c.717T>G p.D239E | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, mutect2
- ADAMTS12 | c.2870C>G p.S957C | Missense Mutation (SNP) | VAF 102/406 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS9 | c.*5G>T | Splice Region (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- ADAMTS9 | c.*3A>T | Splice Region (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- ADCY10 | c.3584C>A p.P1195Q | Missense Mutation (SNP) | VAF 21/333 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by muse, mutect2
- ADCYAP1R1 | c.727T>C p.W243R | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALG13 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2
- ANKRD17 | c.7630G>C p.V2544L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.225); called by muse, mutect2
- ANKRD30B | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.254); called by muse, mutect2
- APOB | c.4391A>T p.Q1464L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2
- APPL2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ARHGAP35 | c.2020G>T p.V674L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2
- BAIAP2L1 | c.26A>T p.N9I | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- BAIAP2L1 | c.25A>T p.N9Y | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2
- BBS9 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- BTK | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAMK2B | c.548C>G p.P183R | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC88B | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, varscan2
- CD274 | c.50A>T p.N17I | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- CDR1 | c.474A>C p.K158N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.035); called by muse, mutect2
- CHD9 | c.6695A>T p.D2232V | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL11A1 | c.3820C>G p.P1274A | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.098); called by muse, mutect2
- COL11A1 | c.2978C>A p.P993H | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL15A1 | c.1348A>T p.T450S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); called by muse, mutect2
- COL3A1 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2
- COL4A5 | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 29/451 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- COL5A2 | c.3018G>T p.M1006I | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.523); called by muse, mutect2
- CSMD3 | c.9761G>T p.S3254I (on ENST00000297405 / NM_001363185.1; = p.S3085I on NM_052900.3) | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- CSMD3 | c.1390G>T p.G464W (on ENST00000297405 / NM_001363185.1; = p.G360W on NM_052900.3) | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CTSC | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2
- CYLD | c.2500A>T p.K834* | Nonsense Mutation (SNP) | VAF 14/233 reads (6%) | called by muse, mutect2
- CYP46A1 | c.282+1G>T p.X94_splice | Splice Site (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- DEFB125 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DLL1 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMD | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.011); called by muse, mutect2
- DNAJC10 | c.2224G>T p.A742S | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.105); called by muse, mutect2
- DOK5 | c.475A>T p.I159F | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- DPEP1 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- DTL | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- DYNC1H1 | c.11860G>T p.D3954Y | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2
- EDARADD | c.68T>C p.M23T (on ENST00000334232 / NM_145861.4; = p.M13T on NM_080738.4) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFHC1 | c.723+7G>A | Splice Region (SNP) | VAF 28/249 reads (11%) | called by muse, mutect2, varscan2
- EGFLAM | c.2008C>A p.H670N | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ESPNL | c.1765C>A p.L589M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAT3 | c.4156G>T p.V1386L | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2
- FAT4 | c.7433C>T p.P2478L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L6 | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- FGG | c.308-4A>T | Splice Region (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- FLNA | c.6652G>C p.G2218R (on ENST00000369850 / NM_001110556.2; = p.G2210R on NM_001456.3) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- FLRT2 | c.1115C>G p.P372R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FNDC7 | c.1482G>C p.E494D | Missense Mutation (SNP) | VAF 35/426 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.22); called by muse, mutect2
- GABRA5 | c.579C>A p.S193R | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- GAS1 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); called by muse, mutect2
- GC | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- GDI1 | c.952del p.Q318Kfs*2 | Frame Shift Del (DEL) | VAF 34/323 reads (11%) | called by mutect2, pindel, varscan2
- GLIPR1L2 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2, varscan2
- GRM1 | c.2486G>A p.C829Y | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRSF1 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GTF2F2 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUK1 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- H2BC6 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.34); called by muse, mutect2
- HHIP | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- IFNA21 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- IGKV3-15 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 32/541 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- IGKV6D-21 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- IGSF5 | c.503G>T p.W168L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL18R1 | c.1459C>A p.Q487K | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.554); called by muse, mutect2
- INTS6L | c.1729A>T p.K577* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- IQCC | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2
- KALRN | c.5045G>C p.R1682P | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNN2 | c.813A>T p.R271S (on ENST00000264773; = p.R483S on NM_021614.4) | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- KIF13B | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- KIF14 | c.4048G>A p.G1350S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- KLHL13 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2
- KLHL13 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- KRT82 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2
- LAMA1 | c.6088G>T p.A2030S | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRP4 | c.5461G>T p.A1821S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- LRRC53 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MAGEE1 | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2
- MGAM2 | c.2666C>T p.T889I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- MS4A14 | c.1923C>A p.C641* | Nonsense Mutation (SNP) | VAF 29/361 reads (8%) | called by muse, mutect2
- MTTP | c.853A>T p.T285S | Missense Mutation (SNP) | VAF 14/449 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, mutect2
- MXRA8 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYH11 | c.2461A>G p.R821G | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYLK2 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); called by muse, mutect2
- MYOM2 | c.2314G>T p.V772L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- NARS2 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- NOL4L | c.477G>T p.A159= | Splice Region (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- NONO | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- NOS2 | c.816G>C p.M272I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); called by muse, mutect2
- NPAP1 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2
- OCRL | c.2334G>T p.E778D | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR10W1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR13C5 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR14A2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR2B6 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR56A3 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 10/287 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR6K6 | c.154G>T p.G52C (on ENST00000368144; = p.G28C on NM_001005184.1) | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PAMR1 | c.690T>G p.H230Q | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.767); called by muse, mutect2
- PANK3 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 19/371 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2
- PCDH15 | c.2922C>A p.Y974* | Nonsense Mutation (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- PCDHA11 | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PCLO | c.3140C>T p.T1047I | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- PIEZO2 | c.5339G>A p.G1780E | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- PLCG2 | c.2789T>A p.L930H | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- PLEKHA6 | c.2317C>A p.P773T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PLTP | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PLXNA1 | c.3877G>C p.A1293P | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PLXNB2 | c.4132G>T p.E1378* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- PLXNB3 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POM121L2 | c.2142del p.R715Efs*19 | Frame Shift Del (DEL) | VAF 28/223 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R17 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKAR2B | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- PRORP | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.437); called by muse, mutect2
- PTGER3 | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.83); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RACGAP1 | c.1831A>G p.S611G | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2
- RASGRP1 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGPD3 | c.4274G>A p.R1425K | Missense Mutation (SNP) | VAF 29/792 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.062); called by muse, mutect2
- RGS7 | c.1068C>G p.S356R | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RRAGB | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- RRP8 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.139); called by muse, mutect2
- RUNX2 | c.1429T>C p.S477P (on ENST00000371438; = p.S455P on NM_001015051.3) | Missense Mutation (SNP) | VAF 100/511 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SEM1 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 36/469 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.556); called by muse, mutect2
- SEMA3E | c.2173G>T p.V725L | Missense Mutation (SNP) | VAF 46/619 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); called by muse, mutect2
- SKAP1 | c.827-2A>T p.X276_splice | Splice Site (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- SLC16A9 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A14 | c.719+8G>T | Splice Region (SNP) | VAF 22/199 reads (11%) | called by muse, mutect2, varscan2
- SLC25A47 | c.678T>A p.C226* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SLC33A1 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2
- SLC35D3 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); called by muse, mutect2
- SLC37A2 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A5 | c.1418C>A p.A473E | Missense Mutation (SNP) | VAF 17/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLFN12L | c.1076C>T p.S359L (on ENST00000260908 / NM_001363830.1; = p.S377L on NM_001195790.1) | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- SLITRK1 | c.1162C>A p.H388N | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2
- SMARCA1 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- SPRTN | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SPTA1 | c.5573T>A p.L1858Q | Missense Mutation (SNP) | VAF 19/455 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2
- SRL | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- STON2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); called by muse, mutect2
- STT3B | c.47A>T p.N16I | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SVIL | c.688T>G p.F230V | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TAF1L | c.402C>A p.Y134* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- TBX2 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- TCP11X2 | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 33/1097 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.073); called by muse, mutect2
- TENM1 | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.884); called by muse, mutect2
- TEX13C | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- TEX45 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); called by muse, mutect2
- TFAP2B | c.492C>A p.D164E | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.935); called by muse, mutect2
- TKTL2 | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.653); called by muse, mutect2
- TMEM132D | c.1588G>T p.V530F | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- TNR | c.780C>A p.D260E | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2
- TRAK1 | c.2282G>T p.R761M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TRAPPC3L | c.241-1G>T p.X81_splice | Splice Site (SNP) | VAF 15/207 reads (7%) | called by muse, mutect2
- TRPC5 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 22/273 reads (8%) | called by muse, mutect2
- VPS13B | c.3081A>T p.T1027= | Splice Region (SNP) | VAF 26/440 reads (6%) | called by muse, mutect2
- WDR17 | c.3784A>T p.T1262S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.118); called by muse, mutect2
- XIRP2 | c.734G>A p.R245K (on ENST00000628543; = p.R420K on NM_152381.6) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XPO4 | c.2443A>G p.I815V | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.085); called by muse, mutect2
- XPO6 | c.3270G>T p.M1090I | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.024); called by muse, mutect2
- ZFHX4 | c.3055A>T p.T1019S | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF333 | c.1715G>T p.S572I | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZNF568 | c.515G>T p.R172I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2
- ZNF622 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- ZNF724 | c.1663A>T p.I555F | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF737 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- ZNF836 | c.842A>T p.K281M | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZP3 | c.714-2A>G p.X238_splice (on ENST00000394857 / NM_001110354.2; = p.X187_splice on NM_007155.6) | Splice Site (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- ABCB4 | c.3345C>A p.L1115= (on ENST00000265723 / NM_018849.3; = p.L1108= on NM_000443.4) | Silent (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- ACACB | c.7266C>T p.N2422= | Silent (SNP) | VAF 6/143 reads (4%) | called by muse, mutect2
- ARFGEF2 | c.72G>C p.V24= | Silent (SNP) | VAF 17/270 reads (6%) | called by muse, mutect2
- ARRB1 | c.84G>A p.V28= | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- ARSH | c.753T>A p.A251= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- AWAT1 | c.465G>T p.V155= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- CEP192 | c.1629G>T p.S543= | Silent (SNP) | VAF 48/312 reads (15%) | catalogued as rs962396010, COSV58067864; called by muse, mutect2, varscan2
- CNGA3 | c.1857G>T p.A619= | Silent (SNP) | VAF 55/405 reads (14%) | catalogued as COSV55625892; called by muse, mutect2, varscan2
- CNTNAP2 | c.3348C>T p.N1116= | Silent (SNP) | VAF 30/273 reads (11%) | called by muse, mutect2, varscan2
- COL6A6 | c.5895T>C p.D1965= | Silent (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- COPE | c.150G>T p.V50= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- DCAF12L1 | c.93G>A p.A31= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as rs1413351626; called by muse, mutect2
- DCAF12L2 | c.559C>T p.L187= | Silent (SNP) | VAF 26/259 reads (10%) | catalogued as COSV63580422; called by muse, mutect2
- DIP2B | c.972G>T p.V324= | Silent (SNP) | VAF 28/297 reads (9%) | called by muse, mutect2, varscan2
- DNAH9 | c.9616C>A p.R3206= | Silent (SNP) | VAF 17/311 reads (5%) | called by muse, mutect2
- DNER | c.474T>A p.A158= | Silent (SNP) | VAF 32/406 reads (8%) | called by muse, mutect2
- DOCK8 | c.921G>T p.L307= | Silent (SNP) | VAF 47/460 reads (10%) | called by muse, mutect2, varscan2
- EIF2S3B | c.765G>T p.R255= | Silent (SNP) | VAF 29/314 reads (9%) | called by muse, mutect2
- ELOVL1 | c.441G>A p.V147= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as rs1478219477; called by muse, mutect2
- ENKD1 | c.51G>T p.T17= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- EPPK1 | c.6309G>T p.L2103= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- EXOC3L1 | c.361C>A p.R121= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs752329601; called by muse, mutect2
- FBXO41 | c.1729C>A p.R577= | Silent (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- FLNA | c.7227C>A p.T2409= (on ENST00000369850 / NM_001110556.2; = p.T2401= on NM_001456.3) | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- GJA3 | c.1200C>A p.T400= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV53834380; called by muse, mutect2
- GUCY2F | c.1170C>T p.F390= | Silent (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- H4C2 | c.198G>T p.V66= | Silent (SNP) | VAF 46/263 reads (17%) | catalogued as rs192365376, COSV55140871, COSV99774872, COSV99775131; called by muse, mutect2, varscan2
- HEPACAM2 | c.321G>T p.L107= (on ENST00000394468 / NM_001039372.4; = p.L95= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/375 reads (7%) | called by muse, mutect2
- HEPH | c.1674G>T p.L558= (on ENST00000343002; = p.L291= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- HPS1 | c.582T>C p.A194= | Silent (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- IGHV3-20 | c.352G>A p.*118= | Silent (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- INTS6L | c.1557T>A p.G519= | Silent (SNP) | VAF 29/248 reads (12%) | called by muse, mutect2
- KCNK18 | c.49C>T p.L17= | Silent (SNP) | VAF 24/296 reads (8%) | catalogued as rs766644058, COSV57971826, COSV57973037; called by muse, mutect2
- LHFPL3 | c.216G>T p.R72= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, varscan2
- LRP1B | c.1887G>T p.L629= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV67222366; called by muse, mutect2
- LRRC32 | c.45C>A p.G15= | Silent (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- MACF1 | c.3393G>T p.L1131= | Silent (SNP) | VAF 14/345 reads (4%) | called by muse, mutect2
- MAP10 | c.1257C>G p.G419= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- MC2R | c.627C>A p.T209= | Silent (SNP) | VAF 14/167 reads (8%) | catalogued as COSV100563224, COSV59620488; called by muse, mutect2
- MYO9A | c.2064C>A p.I688= | Silent (SNP) | VAF 17/355 reads (5%) | called by muse, mutect2
- NIBAN3 | c.1320T>A p.R440= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as COSV99962756; called by muse, mutect2
- NKAPL | c.93G>A p.Q31= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs372800075; called by muse, mutect2, varscan2
- NKX1-2 | c.105G>T p.A35= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2
- NLRP8 | c.1989C>A p.T663= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2
- NWD2 | c.1887C>A p.V629= | Silent (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- NWD2 | c.3711C>A p.A1237= | Silent (SNP) | VAF 16/371 reads (4%) | called by muse, mutect2
- OR10H4 | c.870C>T p.I290= | Silent (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- OR14I1 | c.81G>A p.G27= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs1218532854; called by muse, mutect2, varscan2
- PAPPA2 | c.678C>A p.S226= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as COSV62783452; called by muse, mutect2
- PARP10 | c.2823G>A p.K941= | Silent (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- PCDHAC2 | c.732T>A p.S244= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1554229623; called by mutect2, varscan2
- PCDHB5 | c.2139C>T p.C713= | Silent (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- POU3F4 | c.912C>A p.A304= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV64539509; called by muse, mutect2
- RAET1G | c.744C>A p.T248= | Silent (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- RGS9BP | c.432C>T p.V144= | Silent (SNP) | VAF 9/231 reads (4%) | called by muse, mutect2
- ROBO1 | c.2538C>A p.I846= | Silent (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- RYR2 | c.1740A>G p.V580= | Silent (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- SAG | c.88C>T p.L30= | Silent (SNP) | VAF 18/325 reads (6%) | catalogued as rs758926241; called by muse, mutect2
- SEMA5A | c.1692C>T p.L564= | Silent (SNP) | VAF 41/197 reads (21%) | catalogued as rs1422132414; called by muse, mutect2, varscan2
- SH3RF3 | c.1243C>A p.R415= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- SLC10A3 | c.696C>A p.G232= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- SLC16A2 | c.423C>T p.F141= | Silent (SNP) | VAF 12/285 reads (4%) | called by muse, mutect2
- SLC27A4 | c.126C>T p.I42= | Silent (SNP) | VAF 17/263 reads (6%) | called by muse, mutect2
- SLC35G4 | c.570C>A p.G190= | Silent (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- SLIT3 | c.3162G>T p.L1054= | Silent (SNP) | VAF 8/73 reads (11%) | called by mutect2, varscan2
- SPDYE1 | c.777G>A p.R259= | Silent (SNP) | VAF 30/412 reads (7%) | called by muse, mutect2
- SRP68 | c.951G>T p.L317= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV100326094; called by muse, mutect2
- SRRM4 | c.1239C>T p.S413= | Silent (SNP) | VAF 22/306 reads (7%) | catalogued as COSV99938837; called by muse, mutect2
- TLR4 | c.867A>T p.R289= (on ENST00000355622 / NM_138554.5; = p.R249= on NM_003266.4) | Silent (SNP) | VAF 20/418 reads (5%) | catalogued as COSV62923362; called by muse, mutect2
- TMEM100 | c.99A>C p.T33= | Silent (SNP) | VAF 24/229 reads (10%) | catalogued as rs767649144; called by muse, mutect2
- TNR | c.3132G>T p.P1044= | Silent (SNP) | VAF 25/179 reads (14%) | catalogued as COSV54886417; called by muse, mutect2, varscan2
- TRBV2 | c.114G>T p.V38= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- TTC38 | c.15G>T p.S5= | Silent (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- UGGT2 | c.673C>A p.R225= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as COSV65025845; called by muse, mutect2
- ZFAT | c.2949G>C p.R983= | Silent (SNP) | VAF 20/390 reads (5%) | called by muse, mutect2
- ZFHX4 | c.10332C>A p.V3444= | Silent (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- ZNF479 | c.321C>A p.L107= | Silent (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
- ZNF627 | c.414A>T p.S138= | Silent (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- ZNF713 | c.1173G>T p.G391= (on ENST00000633730 / NM_001366796.2; = p.G404= on NM_182633.3) | Silent (SNP) | VAF 17/222 reads (8%) | called by muse, mutect2
- ABCA11P | n.1244A>G | RNA (SNP) | VAF 27/439 reads (6%) | called by muse, mutect2
- AC064807.1 | n.798A>G | RNA (SNP) | VAF 14/331 reads (4%) | called by muse, mutect2
- AC133561.1 | n.1377G>T | RNA (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- AC244258.1 | n.311-5008T>C | Intron (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2
- ADH5P5 | chr5:23979948 A>G | 5'Flank (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- ARHGEF19 | c.1138-57A>T | Intron (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- ATP7B | c.3061-24G>T | Intron (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- AVPR2 | chrX:153902670 G>T | 5'Flank (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- BOC | c.667+148C>G | Intron (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- CDK5RAP2 | c.5308-27G>T | Intron (SNP) | VAF 14/132 reads (11%) | catalogued as rs370978182, COSV62576940; called by muse, mutect2
- DCTN2 | c.105+3071G>T | Intron (SNP) | VAF 25/372 reads (7%) | called by muse, mutect2
- DRP2 | c.-17C>A | 5'UTR (SNP) | VAF 21/302 reads (7%) | catalogued as rs375729897, COSV65811074; called by muse, mutect2
- DUSP22 | c.508+17A>G | Intron (SNP) | VAF 13/292 reads (4%) | called by muse, mutect2
- FHL1 | c.*1047C>A | 3'UTR (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- GABRA1 | c.-15-35T>A | Intron (SNP) | VAF 9/224 reads (4%) | called by muse, mutect2
- GABRA1 | c.-15-34A>C | Intron (SNP) | VAF 9/228 reads (4%) | called by muse, mutect2
- GNG5P2 | n.66G>T | RNA (SNP) | VAF 50/417 reads (12%) | catalogued as COSV64438447; called by muse, mutect2, varscan2
- GPI | c.805-51G>T | Intron (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- IGKV1D-27 | n.235C>A | RNA (SNP) | VAF 25/410 reads (6%) | called by muse, mutect2
- IL12RB1 | c.-64G>A | 5'UTR (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- ILF2 | c.-24C>T | 5'UTR (SNP) | VAF 23/283 reads (8%) | called by muse, mutect2
- INPP5D | c.665+170G>T | Intron (SNP) | VAF 18/350 reads (5%) | called by muse, mutect2
- LDLRAD4 | c.182-8361G>T | Intron (SNP) | VAF 26/219 reads (12%) | called by muse, mutect2, varscan2
- LINC00632 | n.104+2046C>A | Intron (SNP) | VAF 31/314 reads (10%) | called by muse, mutect2
- LRRC37A5P | n.420G>T | RNA (SNP) | VAF 21/299 reads (7%) | called by muse, mutect2
- MARCHF6 | c.973-11C>G | Intron (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- MLIP | c.613-11260C>A | Intron (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- MRRFP1 | n.229C>A | RNA (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- MRRFP1 | n.228C>A | RNA (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- NFASC | c.1392-44G>T | Intron (SNP) | VAF 14/203 reads (7%) | catalogued as rs1005612850; called by muse, mutect2
- NXF5 | n.807C>A | RNA (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
- NXF5 | n.806C>A | RNA (SNP) | VAF 12/334 reads (4%) | called by muse, mutect2
- OR2W5 | n.525C>A | RNA (SNP) | VAF 44/394 reads (11%) | called by muse, mutect2, varscan2
- PARK7 | c.410-16T>C | Intron (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- PLPPR5 | c.*41C>A | 3'UTR (SNP) | VAF 14/225 reads (6%) | called by muse, mutect2
- PNP | c.-63G>T | 5'UTR (SNP) | VAF 26/239 reads (11%) | catalogued as rs1056366137; called by muse, mutect2, varscan2
- PREPL | chr2:44318104 T>G | 3'Flank (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- PSMD6 | c.146-255G>T | Intron (SNP) | VAF 22/277 reads (8%) | called by muse, mutect2
- REG1A | c.183+44G>T | Intron (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- REG3G | c.76+10C>T | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- RUNX1T1 | chr8:92102891 C>A | 5'Flank (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- SLC6A10P | n.3228G>T | RNA (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2, varscan2
- SPTA1 | c.*13C>A | 3'UTR (SNP) | VAF 14/293 reads (5%) | catalogued as COSV63526074; called by muse, mutect2
- THPO | c.817-15A>G | Intron (SNP) | VAF 21/324 reads (6%) | called by muse, mutect2
- TPT1 | c.102+114G>T | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- TUBB8P7 | n.1419G>T | RNA (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- VCP | c.*23G>T | 3'UTR (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- ZNF280D | chr15:56733698 ins C | 5'Flank (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
